Surgical pathology report (de-identified scan), TCGA case TCGA-29-1692, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1692-01B (Primary Tumor).

Surg Path

CLINICAL HISTORY:
Not provided.

GROSS EXAMINATION:

A. "Omentum biopsy", received unfixed for frozen section AF1. The specimen consists of a 5.0 x 2.0 x 1.0 cm portion of yellow-tan soft friable adipose tissue with an attached 4.5 x 3.0 x 1.5 cm firm lobulated yellow-tan nodule. Portion of the nodule is submitted for frozen section diagnosis AF1. The frozen section remnant is entirely submitted as Block A1. Representative sections of the nodule submitted as Block A2.

B. "Omentum", in formalin. The specimen consists of a 17.0 x 9.0 x 3.0 cm irregular portion of soft yellow-tan fibroadipose tissue. There is a 12.5 x 7.5 x 2.0 cm firm yellow-tan, smooth and glistening poorly defined lesion which on cut section discloses a uniform yellow-tan parenchyma (B1-B4).

C. "Right tube and ovary", in formalin. The specimen consists of a 149 gram, 10.0 x 6.0 x 4.0 cm previously opened ovary with a 4.5 cm portion of attached fallopian tube. The entire ovary is replaced by tumor which is solid with many cysts with multiple thin walled septa and diffuse soft yellow-tan papilliferous projections on the internal surface (C1-3). The serosa is mottled pink-gray with diffuse punctate red discolored areas. The largest 0.4 x 0.3 cm. An attached 3.0 x 1.5 x 1.0 cm unilocular thin walled cyst containing clotted blood on the external surface.

D. "Left tube and ovary", in formalin. The specimen consists of a 9.7 gram, 3.5 x 2.5 x 1.5 cm left ovary with a 5.5 cm portion of attached left fallopian tube including fimbria. The ovarian parenchyma appears unremarkable (D2), but is covered with tumor that is gelatinous gray-tan and friable (D1,3).

INTRA OPERATIVE CONSULTATION:

A. "Omentum biopsy": AF1 - poorly differentiated carcinoma with psammoma bodies, favor ovarian primary.

DIAGNOSIS:

RIGHT OVARY (C): SEROUS ADENOCARCINOMA, FIGO GRADE 2, 10 CM
WITH METASTASES TO

A: OMENTUM

B: OMENTUM

D SEROSA OF LEFT OVARY

FALLOPIAN TUBES, RIGHT (C) AND LEFT (D): NO PATHOLOGIC DIAGNOSIS

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file ca715bf1-4153-423e-88d6-e9e1c46c0c44 (TCGA-29-1692.522E504C-7F53-4E91-A684-FD7B3C54CF06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).